Gene-level copy-number profile of specimen HCM-BROD-0448-C15-85M from HCMI case HCM-BROD-0448-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Age at diagnosis: 78.6 years (28,714 days).
Specimen HCM-BROD-0448-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0d444d0c-818c-409a-96dd-f81eb421ceda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0448-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/a99ad315-f7d2-478e-87bf-b0ddcdad15b6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 128; copy number 2: 13,397; copy number 3: 29,653; copy number 4: 11,058; copy number 5: 3,649; copy number 6: 85; copy number 7: 52; copy number 8: 872; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 927 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,955,364–144,068,350, 2 genes, copy number 7: FAM72C, SRGAP2D.
- chr1:144,412,576–144,474,790, 6 genes, copy number 7: RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1.
- chr6:125,370,034–126,258,355, 11 genes, copy number 7–8: AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11, PPP1R14BP5.
- chr8:12,064,389–12,099,536, 3 genes, copy number 9: DEFB130B, RNA5SP253, DEFB108D.
- chr11:12,377,563–13,924,863, 30 genes, copy number 7: PARVA, AC009806.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683.
- chr13:27,792,483–27,794,768, 1 gene, copy number 7: GSX1.
- chr13:27,828,763–27,828,869, 1 gene, copy number 7: RNU6-73P.
- chr13:28,778,224–28,778,937, 2 genes, copy number 7: AL359741.1, POM121L13P.
- chr13:49,912,702–49,936,490, 1 gene, copy number 7: SPRYD7.
- chr20:30,214,765–64,327,972, 870 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
